CCDI case PBCCKK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/d0a2db44-6257-4647-a069-6154416b4dcf

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 18.4 years (6,716 days).

Biospecimens (3 samples)
- Sample 0DRRTQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRRTY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRRUF: Tissue type: Tumor; Specimen type: Solid Tissue.
